Gene-level copy-number profile of tumor specimen TCGA-HV-AA8X-01A from TCGA case TCGA-HV-AA8X, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.7 years (27,662 days).
Specimen TCGA-HV-AA8X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.8f48b061-260b-4653-9651-53c7796062d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HV-AA8X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cb60821-4d43-4f7e-ba17-725d395c6576

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,574; copy number 2: 46,267; copy number 3: 4,578; copy number 4: 278; copy number 9: 43; copy number 10: 39; copy number 15: 4; copy number 22: 31; copy number 23: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HV-AA8X-01A-11D-A396-01): tumor purity 0.65, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 123 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:124,501–202,303, 1 gene, copy number 23 (within-gene range 1–23): ZNF718.
- chr4:201,409–2,262,109, 79 genes, copy number 10–23 (broad region; genes not listed).
- chr17:31,937,007–32,491,253, 36 genes, copy number 9: SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,495,536–32,531,492, 7 genes, copy number 9: AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.

Autosomal genes at a single copy (total copy number 1): 8,574. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
